Somatic mutation profile of tumor specimen TARGET-10-PARPYH-09A (aliquot TARGET-10-PARPYH-09A-01D) from TARGET case TARGET-10-PARPYH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,105 days).
Specimen TARGET-10-PARPYH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddbda1be-9a8c-40fc-9c63-472568b7ed0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPYH-14A (Bone Marrow Normal), aliquot TARGET-10-PARPYH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c17a4553-f600-4483-836a-c189b90effc4

The open-access MAF lists 108 somatic variants for this specimen: 70 protein-altering or splice-affecting, 17 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 17, Intron 14, Nonsense Mutation 9, 3'UTR 4, Splice Region 3, Splice Site 1, 5'UTR 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR3 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs144228630; called by muse, mutect2, varscan2
- CHMP7 | c.916C>G p.Q306E | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.111); catalogued as rs1466269607; called by muse, mutect2, varscan2
- DLG5 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.784); catalogued as COSV64950275; called by muse, mutect2, varscan2
- DSCAML1 | c.1220G>A p.R407H (on ENST00000321322; = p.R347H on NM_020693.4) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.765); catalogued as rs759795586, COSV58392501; called by muse, mutect2, varscan2
- EPGN | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs377708890; called by muse, varscan2
- ERAL1 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 26/156 reads (17%) | catalogued as COSV99650422; called by muse, mutect2, varscan2
- ERG | c.401T>A p.V134E | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55737982; called by muse, mutect2
- FAT4 | c.5865G>C p.E1955D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100627164; called by muse, mutect2, varscan2
- H3C10 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV60797298, COSV60799019; called by muse, mutect2, varscan2
- HAAO | c.484+8C>T | Splice Region (SNP) | VAF 18/76 reads (24%) | catalogued as rs749984965; called by muse, mutect2, varscan2
- IFNA21 | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV66518447; called by muse, mutect2, varscan2
- IGF1R | c.2752G>C p.D918H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV51305902, COSV51357250; called by muse, mutect2, varscan2
- KATNAL2 | c.1586C>G p.S529* (on ENST00000356157 / NM_001353899.1; = p.S457* on NM_031303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV55298604; called by muse, mutect2, varscan2
- KCNC3 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766890044; called by muse, mutect2, varscan2
- KDM5C | c.1565C>G p.S522C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64772335; called by muse, mutect2, varscan2
- KIAA1755 | c.3286G>C p.D1096H | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV54076586, COSV99642648; called by muse, mutect2, varscan2
- MED12L | c.3088G>A p.D1030N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768404628, COSV56368658, COSV56370540; called by muse, mutect2, varscan2
- MUC16 | c.4065G>C p.K1355N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV67458417; called by muse, mutect2, varscan2
- OR1L1 | c.1062G>T p.M354I (on ENST00000373686; = p.M304I on NM_001005236.3) | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV58936413; called by muse, mutect2, varscan2
- PCDHB15 | c.2350G>C p.E784Q | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); catalogued as rs1272131176, COSV50862616; called by muse, mutect2
- PDE1C | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.898); catalogued as rs1161033445; called by muse, mutect2, varscan2
- RCOR1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs1334393631, COSV51767401; called by muse, mutect2, varscan2
- SPOP | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61653344, COSV61654602; called by muse, mutect2
- TECTA | c.23G>C p.R8T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV50688513; called by muse, mutect2, varscan2
- TGM6 | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.389); catalogued as rs769042038, COSV99171718; called by muse, mutect2, varscan2
- TRAPPC12 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV60846970; called by muse, mutect2
- UNCX | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100310234; called by muse, mutect2, varscan2
- USP51 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV72351629, COSV72351917; called by muse, mutect2, varscan2
- ZNF462 | c.5071G>A p.E1691K | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV52952548; called by muse, mutect2, varscan2
- A2M | c.2042C>G p.S681* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- ALDH18A1 | c.1574C>G p.S525* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- ALPK3 | c.681G>C p.L227F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, varscan2
- ALPK3 | c.758G>C p.G253A | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, varscan2
- ALPK3 | c.933G>C p.E311D | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ALPK3 | c.1332G>C p.E444D | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF4 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARNT2 | c.1971G>A p.W657* | Nonsense Mutation (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2
- C7orf33 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CBX1 | c.318+5G>C | Splice Region (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- CCDC168 | c.5260G>C p.D1754H | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC191 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CMYA5 | c.8032G>C p.E2678Q | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CPSF2 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- EAF2 | c.106_106+2del p.X36_splice | Splice Site (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel*
- ENTPD8 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FAM160A1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- FGD6 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRB1 | c.720G>C p.K240N | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GCC2 | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- HEATR9 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ITIH2 | c.1955C>G p.S652* | Nonsense Mutation (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- KMT2C | c.6878C>T p.S2293F | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MYBL2 | c.1988G>A p.W663* | Nonsense Mutation (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- NFATC2 | c.2011C>G p.Q671E | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NRXN2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- OR1C1 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PDLIM5 | c.1482G>C p.L494F | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP1R42 | c.539T>A p.L180H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RADIL | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SNAPC4 | c.4271C>G p.T1424R | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.114); called by muse, mutect2
- STON2 | c.1999G>C p.E667Q (on ENST00000649389 / NM_001366849.2; = p.E610Q on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SYNE2 | c.-51-3C>T | Splice Region (SNP) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- TCTE1 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, varscan2
- TCTE1 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TLR3 | c.819G>A p.W273* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- TMEM71 | c.670C>G p.H224D (on ENST00000523829 / NM_001382398.1; = p.H205D on NM_144649.3) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- WNT9B | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); called by muse, mutect2
- XRN1 | c.1304G>C p.R435T | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2
- ZBTB44 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.279); called by muse, mutect2
- ZNF559-ZNF177 | c.767G>A p.R256K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ADCY2 | c.2682G>A p.P894= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs201615098; called by muse, varscan2
- AGO1 | c.2193G>A p.G731= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- BCL11A | c.357A>T p.G119= | Silent (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- CAD | c.579C>G p.L193= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99255266; called by muse, mutect2, varscan2
- DCAF1 | c.4410C>T p.D1470= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as rs370422608; called by muse, mutect2, varscan2
- FGFR2 | c.2316C>T p.L772= | Silent (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- IGKV1D-37 | chr2:89885215 del C | Silent (DEL) | VAF 19/35 reads (54%) | called by mutect2, varscan2
- KIAA1755 | c.3072G>C p.L1024= | Silent (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- LYRM4 | c.243G>A p.L81= | Silent (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- MYO1B | c.705G>C p.L235= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- PLB1 | c.756G>T p.V252= | Silent (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- POLDIP2 | c.690C>G p.L230= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- PRMT6 | c.81G>A p.A27= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV63655090; called by muse, mutect2, varscan2
- SSX2IP | c.624G>A p.L208= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- VPS29 | c.147C>G p.L49= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs776447100; called by muse, mutect2, varscan2
- VWA2 | c.1749C>T p.F583= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs143465186; called by muse, mutect2, varscan2
- ZDHHC11 | c.816C>G p.L272= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as COSV52066008, COSV52070000, COSV99363788; called by muse, mutect2
- API5 | c.1492+45G>A | Intron (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- BET1 | c.201+167G>C | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- CCDC180 | c.-94G>C | 5'UTR (SNP) | VAF 17/65 reads (26%) | catalogued as COSV63827144; called by muse, mutect2, varscan2
- CMTM1 | c.81+94C>T | Intron (SNP) | VAF 54/106 reads (51%) | catalogued as rs774917241, COSV99862677; called by muse, mutect2, varscan2
- CPLANE1 | c.*4622G>C | 3'UTR (SNP) | VAF 6/112 reads (5%) | catalogued as COSV57055825; called by muse, mutect2
- ELP1 | c.3223-22C>G | Intron (SNP) | VAF 14/33 reads (42%) | catalogued as rs1554692209; called by muse, mutect2, varscan2
- EYS | c.1767-7317C>T | Intron (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
- FAM151B | c.671+54G>C | Intron (SNP) | VAF 20/98 reads (20%) | catalogued as rs542935382; called by muse, mutect2, varscan2
- FER1L4 | n.2906C>G | RNA (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- HTT | c.1868-121G>A | Intron (SNP) | VAF 7/28 reads (25%) | called by muse, varscan2
- KIAA0100 | c.6289-72G>C | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- LCOR | c.*2506A>C | 3'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- MS4A8 | c.534+54G>C | Intron (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- NEU1 | c.798+52G>A | Intron (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- NHEJ1 | c.*64G>C | 3'UTR (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- NTN5 | c.1024+33G>A | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- PKP1 | c.1295+105G>C | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- RAB33B | c.*8T>C | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- WBP2NL | chr22:42032655 T>C | 3'Flank (SNP) | VAF 6/12 reads (50%) | catalogued as rs1020753698; called by muse, mutect2, varscan2
- YIF1B | c.58+69C>T | Intron (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- ZNF419 | c.34-104G>A | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
